Somatic mutation profile of tumor specimen TCGA-18-4086-01A (aliquot TCGA-18-4086-01A-01D-1352-08) from TCGA case TCGA-18-4086, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 65.0 years (23,731 days).
Specimen TCGA-18-4086-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f39c94d-0b48-417a-a53d-61334a588ead.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-4086-11A (Solid Tissue Normal), aliquot TCGA-18-4086-11A-01D-1352-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/428de594-0eed-4d5e-84b9-8b04ea2a3e0e

The open-access MAF lists 175 somatic variants for this specimen: 125 protein-altering or splice-affecting, 43 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 97, Silent 43, Nonsense Mutation 11, Splice Site 8, Frame Shift Del 6, Intron 3, Splice Region 3, RNA 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.673-1G>T p.X225_splice | Splice Site (SNP) | VAF 36/58 reads (62%) | hotspot (GDC flag); catalogued as rs878854073, CS011061, COSV52662773, COSV52705331, COSV52707963, COSV53154363; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACCSL | c.688C>T p.R230* | Nonsense Mutation (SNP) | VAF 22/89 reads (25%) | catalogued as rs202077224; called by muse, mutect2, varscan2
- ADAM2 | c.2175-2A>T p.X725_splice | Splice Site (SNP) | VAF 13/64 reads (20%) | catalogued as COSV55862974; called by muse, mutect2, varscan2
- ALK | c.2416C>G p.R806G | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.499); catalogued as COSV66590467; called by muse, mutect2, varscan2
- AMD1 | c.864+1G>A p.X288_splice | Splice Site (SNP) | VAF 17/56 reads (30%) | catalogued as COSV64388325; called by muse, mutect2, varscan2
- ANK2 | c.4396G>C p.E1466Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52189839; called by muse, mutect2, varscan2
- ANO5 | c.803A>G p.N268S | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as rs769560800, COSV61090516; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF10 | c.1725+1G>C p.X575_splice (on ENST00000398564; = p.X550_splice on NM_014629.4) | Splice Site (SNP) | VAF 10/34 reads (29%) | catalogued as COSV50680304; called by muse, mutect2, varscan2
- ASPM | c.5801G>T p.W1934L | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV54136514, COSV54139172; called by muse, mutect2, varscan2
- ATP2B2 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59507849; called by muse, mutect2, varscan2
- ATP5F1C | c.819G>C p.L273F | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV59623006; called by muse, varscan2
- BIVM-ERCC5 | c.1567C>T p.R523* | Nonsense Mutation (SNP) | VAF 8/84 reads (10%) | catalogued as COSV63247467; called by muse, mutect2
- CACNA2D3 | c.1303C>A p.L435I | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.766); catalogued as COSV55584103; called by muse, mutect2, varscan2
- CAPN12 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.878); catalogued as COSV100185086, COSV61018794; called by muse, mutect2, varscan2
- CAPN3 | c.381G>T p.G127= | Splice Region (SNP) | VAF 51/174 reads (29%) | catalogued as COSV100532802, COSV58826613; called by muse, mutect2, varscan2
- CAPN3 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 50/172 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58826627; called by muse, mutect2, varscan2
- CARS1 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 45/141 reads (32%) | catalogued as COSV53461297; called by muse, mutect2, varscan2
- CBARP | c.158C>T p.T53M (on ENST00000382477; = p.T59M on NM_152769.3) | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.799); catalogued as rs374536448; called by muse, mutect2, varscan2
- CCDC30 | c.1729G>C p.E577Q (on ENST00000340612; = p.E534Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59609543; called by muse, varscan2
- CD84 | c.425T>A p.M142K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV60871000; called by muse, mutect2, varscan2
- CDH18 | c.1889T>A p.V630E | Missense Mutation (SNP) | VAF 66/354 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV56962725; called by muse, mutect2, varscan2
- CENPE | c.4219G>T p.E1407* | Nonsense Mutation (SNP) | VAF 20/104 reads (19%) | catalogued as rs1440432920, COSV54378617; called by muse, mutect2, varscan2
- CHD6 | c.5794G>T p.A1932S | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs113050531, COSV64691685; called by muse, mutect2, varscan2
- CNGB3 | c.1972C>A p.P658T | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV60698825; called by muse, mutect2, varscan2
- COCH | c.685G>C p.A229P (on ENST00000216361 / NM_001347720.1; = p.A164P on NM_004086.3) | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV53553132; called by muse, mutect2, varscan2
- COL5A2 | c.691-2A>G p.X231_splice | Splice Site (SNP) | VAF 6/47 reads (13%) | catalogued as COSV66415619; called by muse, mutect2
- COL8A1 | c.1705G>T p.G569* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV53743308; called by muse, mutect2, varscan2
- CPAMD8 | c.614C>T p.P205L (on ENST00000651564; = p.P158L on NM_015692.5) | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV52240125; called by muse, mutect2, varscan2
- CROT | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.468); catalogued as COSV58977008; called by muse, mutect2, varscan2
- CRYL1 | c.846+1G>T p.X282_splice | Splice Site (SNP) | VAF 40/122 reads (33%) | catalogued as COSV53421650; called by muse, mutect2, varscan2
- CTNNA2 | c.105G>A p.V35= | Splice Region (SNP) | VAF 9/47 reads (19%) | catalogued as COSV63603906; called by muse, mutect2
- DAND5 | c.340G>A p.G114S | Missense Mutation (SNP) | VAF 33/123 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs765612939, COSV57684643; called by muse, mutect2, varscan2
- DISP3 | c.3829C>T p.Q1277* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV53837954; called by muse, mutect2
- DLG1 | c.994A>G p.S332G | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58391915; called by muse, mutect2, varscan2
- DNAAF2 | c.391T>A p.Y131N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.246); catalogued as COSV53572230; called by muse, mutect2, varscan2
- DNAH3 | c.10552T>C p.C3518R | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54553758; called by muse, mutect2, varscan2
- ELP3 | c.824A>G p.K275R | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.534); catalogued as COSV56461652; called by muse, mutect2, varscan2
- EPB41L1 | c.1756G>C p.D586H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as COSV52445347; called by muse, mutect2, varscan2
- FBXL17 | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as COSV62862334; called by muse, mutect2, varscan2
- FERD3L | c.82C>A p.P28T | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV51764429; called by muse, mutect2, varscan2
- FLG | c.3401C>A p.T1134N | Missense Mutation (SNP) | VAF 143/473 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV64249983; called by muse, mutect2, varscan2
- GLUD2 | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV60153238; called by muse, mutect2, varscan2
- GNB3 | c.70G>C p.A24P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.161); catalogued as COSV51836606; called by muse, mutect2, varscan2
- GPR137B | c.884G>C p.G295A | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63991747; called by muse, mutect2, varscan2
- GREM1 | c.186A>T p.Q62H | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55716371; called by muse, mutect2, varscan2
- GRWD1 | c.621C>G p.I207M | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV53520897; called by muse, mutect2, varscan2
- HECW1 | c.2014G>T p.G672C | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.319); catalogued as COSV67840560; called by muse, mutect2, varscan2
- HERC2 | c.6161A>C p.K2054T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.05); catalogued as COSV55351301; called by muse, mutect2, varscan2
- ICE2 | c.133G>T p.V45F | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0.034); catalogued as COSV55034163; called by muse, varscan2
- IPP | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV63434050; called by muse, mutect2
- KBTBD2 | c.1379C>A p.S460Y | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.194); catalogued as COSV58363511, COSV58364373; called by muse, mutect2, varscan2
- KCNJ9 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63632471; called by muse, mutect2, varscan2
- KCNN2 | c.673G>T p.A225S (on ENST00000264773; = p.A437S on NM_021614.4) | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.629); catalogued as COSV53299566; called by muse, mutect2, varscan2
- KRTAP10-7 | c.408C>A p.C136* | Nonsense Mutation (SNP) | VAF 38/202 reads (19%) | catalogued as COSV59113456; called by muse, mutect2, varscan2
- LCMT2 | c.488G>T p.R163L | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV59791887; called by muse, mutect2, varscan2
- LRP1B | c.12431G>C p.G4144A | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs1277239833, COSV67182543, COSV67277456; called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.579G>C p.R193S | Missense Mutation (SNP) | VAF 25/164 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV65442563, COSV65443230; called by muse, mutect2, varscan2
- MAP7D1 | c.2159G>C p.R720P | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60218649, COSV60219335; called by muse, mutect2, varscan2
- MEPE | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.033); catalogued as COSV63074593; called by muse, mutect2, varscan2
- MORC1 | c.2780T>A p.L927* | Nonsense Mutation (SNP) | VAF 27/133 reads (20%) | catalogued as COSV51731682; called by muse, mutect2, varscan2
- MT1H | c.95-2A>T p.X32_splice | Splice Site (SNP) | VAF 24/134 reads (18%) | catalogued as COSV60091650; called by muse, mutect2, varscan2
- MT1H | c.95-1G>T p.X32_splice | Splice Site (SNP) | VAF 24/137 reads (18%) | catalogued as COSV60091658; called by muse, mutect2, varscan2
- MTMR11 | c.715A>G p.I239V (on ENST00000439741 / NM_001145862.2; = p.I167V on NM_181873.3) | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1021930989, COSV63808819; called by muse, mutect2, varscan2
- MUC16 | c.6880G>T p.D2294Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV67495604; called by muse, mutect2, varscan2
- MYEOV | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.146); catalogued as COSV58293634; called by muse, varscan2
- MYH11 | c.4290C>A p.D1430E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.196); catalogued as COSV55570615; called by muse, mutect2, varscan2
- NAA30 | c.650G>C p.R217P | Missense Mutation (SNP) | VAF 100/191 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV53649814; called by muse, mutect2, varscan2
- NCKAP5 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs777479794, COSV58447015, COSV58474004; called by muse, mutect2
- NDUFAF4 | c.346A>T p.I116F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV60214637; called by muse, mutect2, varscan2
- NEK8 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs140363905; called by muse, mutect2, varscan2
- NEUROG2 | c.517C>G p.H173D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV57638229; called by muse, mutect2
- OR2T12 | c.171G>T p.M57I | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV58779684; called by muse, mutect2, varscan2
- OR5L1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV61734726, COSV61735495; called by muse, mutect2
- PACRGL | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.095); catalogued as COSV54844815; called by muse, mutect2
- PARD6A | c.441C>G p.D147E | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54666465, COSV54670598; called by muse, mutect2, varscan2
- PIK3C2G | c.3427G>T p.A1143S (on ENST00000676171; = p.A1102S on NM_004570.5) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56835144; called by muse, mutect2, varscan2
- PKHD1 | c.11500C>T p.P3834S | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64400743; called by muse, mutect2, varscan2
- POU1F1 | c.251A>G p.H84R | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.197); catalogued as COSV60157614; called by muse, mutect2, varscan2
- PPDPFL | c.138G>C p.L46F | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as rs1426291201, COSV57461926, COSV57462269; called by muse, mutect2, varscan2
- PTPRE | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54559291; called by muse, mutect2, varscan2
- PTPRN | c.2216G>T p.R739L | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55352497; called by muse, mutect2, varscan2
- RB1 | c.203A>G p.D68G | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.197); catalogued as CD982921, COSV57328342; called by muse, mutect2, varscan2
- RIMKLB | c.581A>T p.K194M | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV55240217; called by muse, mutect2, varscan2
- RPS6KC1 | c.2333T>C p.V778A | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs769130007, COSV65302962; called by muse, mutect2, varscan2
- SACS | c.11733C>A p.S3911R | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV66547035; called by muse, mutect2, varscan2
- SAMD3 | c.497C>G p.P166R | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60777964; called by muse, mutect2, varscan2
- SAXO2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as COSV59755500; called by muse, mutect2, varscan2
- SEPTIN1 | c.482T>C p.F161S (on ENST00000321367; = p.F114S on NM_052838.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV58443999; called by muse, mutect2, varscan2
- SIAH3 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.86); catalogued as COSV101247945, COSV68553407; called by muse, mutect2, varscan2
- SIX2 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57392389; called by muse, mutect2, varscan2
- SLC18A1 | c.197C>A p.A66D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.033); catalogued as COSV52351373; called by muse, mutect2, varscan2
- SLC26A4 | c.1577G>T p.S526I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV55920335; called by muse, mutect2, varscan2
- SLC35G1 | c.778G>A p.V260I (on ENST00000427197 / NM_001134658.3; = p.V259I on NM_153226.4) | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV65055761; called by muse, mutect2, varscan2
- SLC52A3 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV54079463; called by muse, mutect2, varscan2
- SLC9A2 | c.1867A>T p.S623C | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV52138272; called by muse, mutect2, varscan2
- SPAG6 | c.172C>G p.Q58E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV57624213; called by muse, mutect2, varscan2
- SPATA31E1 | c.2746G>T p.V916L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57795547; called by muse, mutect2, varscan2
- SPG11 | c.4189C>A p.P1397T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56002412; called by muse, mutect2, varscan2
- SPG11 | c.4188C>A p.S1396R | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); catalogued as COSV56002432; called by muse, mutect2, varscan2
- ST8SIA6 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV66461752; called by muse, varscan2
- SURF2 | c.358G>T p.G120W | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV64332745; called by muse, mutect2, varscan2
- SYNE2 | c.19294G>A p.E6432K | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs776342676, COSV59971212; called by mutect2, varscan2
- SYNE3 | c.580C>T p.Q194* | Nonsense Mutation (SNP) | VAF 44/109 reads (40%) | catalogued as COSV62082920; called by muse, mutect2, varscan2
- TAGAP | c.356A>C p.E119A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57853236; called by muse, mutect2, varscan2
- TAP1 | c.325C>G p.P109A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV62755848; called by muse, mutect2, varscan2
- TBATA | c.972G>A p.E324= | Splice Region (SNP) | VAF 13/137 reads (9%) | catalogued as COSV54721918; called by muse, mutect2, varscan2
- TECTA | c.719A>C p.N240T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50809944; called by muse, mutect2, varscan2
- TEK | c.3349G>C p.D1117H | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1298050036, COSV66234970; called by muse, mutect2, varscan2
- TIMD4 | c.1090G>C p.D364H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50860626; called by muse, mutect2, varscan2
- TNKS | c.3599G>A p.R1200Q | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs762718942, COSV60066711; called by muse, mutect2, varscan2
- TRIM14 | c.58T>C p.C20R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV58356184; called by muse, mutect2, varscan2
- USP35 | c.1798T>G p.F600V | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71573273; called by muse, mutect2, varscan2
- WDR25 | c.1036C>T p.H346Y | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.36); catalogued as rs1290024917, COSV58940039; called by muse, mutect2, varscan2
- XIRP2 | c.9670G>T p.E3224* (on ENST00000628543; = p.E3399* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 41/120 reads (34%) | catalogued as rs761769660, COSV54735943; called by muse, mutect2, varscan2
- ZNF425 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as rs756481389, COSV65201317, COSV65202753; called by muse, mutect2, varscan2
- ZNF518B | c.831G>T p.L277F | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV58724928; called by muse, mutect2, varscan2
- ZPLD1 | c.461G>A p.S154N (on ENST00000466937 / NM_001329788.1; = p.S170N on NM_175056.2) | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60356226; called by muse, mutect2, varscan2
- A1BG | c.730_736del p.R244Gfs*21 | Frame Shift Del (DEL) | VAF 9/57 reads (16%) | called by mutect2, varscan2
- CLGN | c.1024del p.E342Rfs*21 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | called by mutect2, varscan2
- GOLGB1 | c.8231_8249del p.Q2744Pfs*8 | Frame Shift Del (DEL) | VAF 50/278 reads (18%) | called by mutect2, varscan2
- MFSD11 | c.941del p.G314Afs*7 | Frame Shift Del (DEL) | VAF 76/238 reads (32%) | called by mutect2, varscan2
- MRPL9 | c.713del p.V238Gfs*15 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | called by mutect2, varscan2
- PIP4K2B | c.286A>C p.K96Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PPP4R1 | c.765del p.R256Dfs*44 (on ENST00000400556 / NM_001042388.3; = p.R239Dfs*44 on NM_005134.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/51 reads (35%) | called by mutect2, varscan2
- SP140 | c.1942G>T p.G648W | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACTL8 | c.960C>G p.V320= | Silent (SNP) | VAF 5/106 reads (5%) | catalogued as COSV64862781; called by muse, mutect2
- ADGRF1 | c.1788C>T p.S596= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV51947964; called by muse, mutect2, varscan2
- AKR1A1 | c.78T>C p.P26= | Silent (SNP) | VAF 16/165 reads (10%) | catalogued as COSV61087742; called by muse, mutect2
- ALOX15B | c.1605G>T p.R535= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as COSV66480186; called by muse, mutect2, varscan2
- ANXA3 | c.897A>G p.L299= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1387371243, COSV53717555; called by muse, mutect2, varscan2
- AR | c.1608G>C p.G536= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV65964381; called by muse, mutect2, varscan2
- C6orf15 | c.648G>T p.V216= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV52540092; called by muse, mutect2, varscan2
- CD209 | c.66C>T p.G22= | Silent (SNP) | VAF 141/592 reads (24%) | catalogued as COSV52659272; called by muse, mutect2, varscan2
- CEP135 | c.2388G>C p.R796= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV57262889; called by muse, mutect2, varscan2
- CHPF | c.597T>G p.P199= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV60536913; called by muse, mutect2, varscan2
- COP1 | c.576C>A p.L192= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV58166129, COSV58176588; called by muse, mutect2, varscan2
- CSMD3 | c.8670G>T p.G2890= (on ENST00000297405 / NM_001363185.1; = p.G2721= on NM_052900.3) | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as rs944219703, COSV52326816; called by muse, mutect2, varscan2
- DNMT3A | c.1596C>T p.G532= | Silent (SNP) | VAF 29/98 reads (30%) | catalogued as rs1282314163, COSV53079242; called by muse, mutect2, varscan2
- DTX3L | c.312G>C p.L104= | Silent (SNP) | VAF 33/132 reads (25%) | catalogued as COSV56144438, COSV56145642; called by muse, mutect2, varscan2
- GAK | c.315G>C p.A105= | Silent (SNP) | VAF 33/95 reads (35%) | catalogued as COSV58510085; called by muse, mutect2, varscan2
- GDF10 | c.435G>A p.A145= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs781890832; called by muse, mutect2, varscan2
- GPAM | c.2283C>A p.T761= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV62082717; called by muse, mutect2, varscan2
- GSTT2B | c.168G>T p.T56= | Silent (SNP) | VAF 36/220 reads (16%) | catalogued as COSV51960265; called by muse, varscan2
- HIVEP2 | c.1833T>C p.H611= | Silent (SNP) | VAF 87/211 reads (41%) | catalogued as rs760826254, COSV50069130; called by muse, mutect2, varscan2
- KIF17 | c.3030C>T p.I1010= | Silent (SNP) | VAF 18/153 reads (12%) | catalogued as COSV56116747, COSV56122283; called by muse, mutect2, varscan2
- LAMA2 | c.855G>C p.G285= | Silent (SNP) | VAF 67/231 reads (29%) | catalogued as COSV101370224, COSV70349926, COSV70355648; called by muse, mutect2, varscan2
- LGR4 | c.1753T>C p.L585= | Silent (SNP) | VAF 32/86 reads (37%) | catalogued as COSV64866331; called by muse, mutect2, varscan2
- LILRB4 | c.1227G>A p.Q409= (on ENST00000391733 / NM_001278428.3; = p.Q408= on NM_001278426.3) | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV54403775; called by muse, mutect2, varscan2
- MED13L | c.249A>G p.L83= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs138672862; called by muse, mutect2, varscan2
- MKRN3 | c.471G>C p.A157= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV58810296, COSV58812359; called by muse, mutect2, varscan2
- MORC1 | c.2781G>A p.L927= | Silent (SNP) | VAF 27/132 reads (20%) | catalogued as COSV51731673; called by muse, mutect2, varscan2
- MYBL2 | c.864G>T p.L288= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as COSV53833905; called by muse, mutect2, varscan2
- MYOG | c.312G>A p.L104= | Silent (SNP) | VAF 30/122 reads (25%) | catalogued as COSV54096803; called by muse, mutect2, varscan2
- NT5C1A | c.930T>A p.A310= | Silent (SNP) | VAF 65/182 reads (36%) | catalogued as COSV52496460; called by muse, mutect2, varscan2
- OR4F15 | c.210T>C p.D70= | Silent (SNP) | VAF 70/338 reads (21%) | catalogued as rs1370538689, COSV59970421; called by muse, mutect2, varscan2
- OR5D18 | c.786G>T p.V262= | Silent (SNP) | VAF 24/86 reads (28%) | catalogued as COSV61738721; called by muse, mutect2, varscan2
- PCLO | c.8361T>A p.P2787= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV61668204; called by muse, mutect2, varscan2
- PIH1D1 | c.780G>T p.P260= | Silent (SNP) | VAF 35/141 reads (25%) | catalogued as COSV51808673; called by muse, mutect2, varscan2
- PLEKHG4 | c.1122A>T p.L374= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV64614293; called by muse, mutect2, varscan2
- POM121L12 | c.267G>A p.P89= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs772385441, COSV101374858, COSV68692323; called by muse, mutect2, varscan2
- RELN | c.6285G>A p.G2095= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV59034907; called by muse, varscan2
- RFX4 | c.864G>A p.K288= (on ENST00000392842 / NM_213594.3; = p.K194= on NM_032491.6) | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV57581739; called by muse, mutect2, varscan2
- RFX6 | c.1701T>A p.T567= | Silent (SNP) | VAF 44/164 reads (27%) | catalogued as COSV60589030; called by muse, mutect2, varscan2
- SFRP5 | c.648G>A p.G216= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as COSV56605255; called by muse, mutect2, varscan2
- SLC35C1 | c.903G>T p.T301= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs150743224; ClinVar: likely benign; called by muse, mutect2, varscan2
- SUMF1 | c.312T>C p.D104= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV55996173; called by muse, mutect2, varscan2
- TROAP | c.2133G>A p.L711= | Silent (SNP) | VAF 19/84 reads (23%) | catalogued as COSV57746058; called by muse, mutect2, varscan2
- ZNF804B | c.1717T>C p.L573= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV60856732; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85485G>C | Intron (SNP) | VAF 11/23 reads (48%) | catalogued as COSV72283549; called by muse, mutect2, varscan2
- NOX5 | c.*2C>A | 3'UTR (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- PPP1R8 | c.117+1732A>G | Intron (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-12790A>T | Intron (SNP) | VAF 18/50 reads (36%) | catalogued as COSV67450524; called by muse, mutect2, varscan2
- SNORD115-7 | n.46A>T | RNA (SNP) | VAF 73/315 reads (23%) | called by muse, mutect2, varscan2
- SNORD116-17 | n.1G>T | RNA (SNP) | VAF 33/115 reads (29%) | called by muse, mutect2, varscan2
- TMEM183B | n.186T>A | RNA (SNP) | VAF 89/242 reads (37%) | called by muse, mutect2, varscan2
